Somatic mutation profile of tumor specimen C3N-01524-03 (aliquot CPT0077310009) from CPTAC case C3N-01524, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 61.8 years (22,558 days).
Specimen C3N-01524-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e7936ad-7795-43e3-929f-5c31f2b3dcd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01524-71 (Blood Derived Normal), aliquot CPT0077410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7336d874-16b0-4f82-9cb0-96db287e76a6

The open-access MAF lists 117 somatic variants for this specimen: 84 protein-altering or splice-affecting, 18 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 18, Intron 6, 3'UTR 6, Frame Shift Del 5, Nonsense Mutation 5, 5'Flank 2, Frame Shift Ins 2, RNA 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 84/186 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs869025631, CD141834, CM951280, HM971583, COSV56542714, COSV56543921; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C1orf87 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64596508; called by muse, mutect2, varscan2
- CEMP1 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV99566116; called by muse, varscan2
- CEP41 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 107/397 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs782784827, COSV56219159; called by muse, mutect2, varscan2
- CHRNA2 | c.860T>C p.F287S | Missense Mutation (SNP) | VAF 117/410 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060503073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLSTN3 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs148818256, COSV99867181; called by muse, varscan2
- CNTN3 | c.2237C>A p.T746N | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.296); catalogued as COSV55185594; called by muse, varscan2
- CP | c.2536G>C p.V846L | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.324); catalogued as rs1321940071; called by muse, mutect2, varscan2
- DPYSL4 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); catalogued as COSV58308937; called by muse, mutect2, varscan2
- HPS3 | c.980C>A p.T327K | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV56054075; called by muse, mutect2, varscan2
- IGLV4-3 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.387); catalogued as rs754142164; called by muse, mutect2, varscan2
- KIF13A | c.4235A>G p.Q1412R | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs771426174; called by muse, mutect2, varscan2
- KRTAP9-4 | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 111/391 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1336276656, COSV100484848; called by muse, mutect2, varscan2
- MUC17 | c.6628A>C p.M2210L | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs1016884814; called by muse, mutect2, varscan2
- MYL7 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56267371; called by muse, mutect2, varscan2
- PACS2 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs1209362754; called by muse, mutect2, varscan2
- PPFIA2 | c.1700C>A p.S567Y | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.323); catalogued as COSV61035926; called by muse, mutect2, varscan2
- PRMT8 | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54212189; called by muse, mutect2, varscan2
- PRPF8 | c.5624A>G p.H1875R | Missense Mutation (SNP) | VAF 72/600 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV59261977, COSV59266339; called by muse, mutect2, varscan2
- RHOB | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99695119; called by muse, mutect2
- RTTN | c.4105G>A p.A1369T | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV99731035; called by muse, mutect2, varscan2
- UBE2L3 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100641576; called by muse, mutect2
- ZNF527 | c.482G>C p.R161T | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV62236139; called by muse, mutect2, varscan2
- ACY3 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- AKAP12 | c.2608G>T p.E870* | Nonsense Mutation (SNP) | VAF 24/220 reads (11%) | called by muse, mutect2, varscan2
- AOPEP | c.2083A>T p.K695* (on ENST00000375315 / NM_001193329.1; = p.K596* on NM_032823.5) | Nonsense Mutation (SNP) | VAF 60/194 reads (31%) | called by muse, mutect2, varscan2
- ATP5IF1 | c.296T>G p.I99S | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4120A>C p.T1374P | Missense Mutation (SNP) | VAF 78/353 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CAMTA1 | c.3131A>C p.K1044T | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CCDC9 | c.1411T>A p.F471I | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK13 | c.2861A>C p.K954T | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CIPC | c.976A>T p.K326* | Nonsense Mutation (SNP) | VAF 89/280 reads (32%) | called by muse, mutect2, varscan2
- CIRBP | c.213dup p.V72Cfs*45 | Frame Shift Ins (INS) | VAF 40/203 reads (20%) | called by mutect2, pindel, varscan2
- CNDP2 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CNDP2 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- CPLX4 | c.313dup p.D105Gfs*8 | Frame Shift Ins (INS) | VAF 51/179 reads (28%) | called by mutect2, pindel, varscan2
- CTNNA1 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 79/410 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUBN | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CYFIP2 | c.2794_2795del p.F932Rfs*58 (on ENST00000616178 / NM_001291722.2; = p.F907Rfs*58 on NM_014376.4) | Frame Shift Del (DEL) | VAF 61/314 reads (19%) | called by mutect2, pindel, varscan2
- DEPDC1 | c.165C>A p.D55E | Missense Mutation (SNP) | VAF 80/311 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAJC11 | c.940T>G p.F314V | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DSCAM | c.1237T>C p.F413L | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EPHB2 | c.2104A>C p.M702L (on ENST00000400191 / NM_001309193.2; = p.M703L on NM_004442.7) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- EXOSC2 | c.773A>T p.Y258F | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FAM120B | c.1638G>T p.M546I | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.39); called by mutect2, varscan2
- FSIP2 | c.14243T>C p.I4748T | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- GPHN | c.1664T>A p.L555H (on ENST00000315266 / NM_001377519.1; = p.L588H on NM_020806.5) | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- IRAG1 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNF1 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- KCNH3 | c.1690del p.E564Sfs*76 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | called by mutect2, pindel*
- KCNH5 | c.629A>C p.Y210S | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCTD9 | c.593_599del p.S198Yfs*11 | Frame Shift Del (DEL) | VAF 37/214 reads (17%) | called by mutect2, pindel, varscan2
- KIF20B | c.1937T>A p.V646D | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- KIF5C | c.1044del p.E349Rfs*8 | Frame Shift Del (DEL) | VAF 21/114 reads (18%) | called by mutect2, pindel, varscan2
- KRTAP5-11 | c.336C>A p.C112* | Nonsense Mutation (SNP) | VAF 156/545 reads (29%) | called by muse, mutect2, varscan2
- LLGL1 | c.3049A>T p.T1017S | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP1A | c.3745C>T p.H1249Y | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MEGF11 | c.1936T>A p.S646T | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MTHFSD | c.349C>G p.Q117E (on ENST00000360900 / NM_001159377.2; = p.Q116E on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAPG | c.2852G>T p.R951I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- P4HA2 | c.288C>G p.D96E | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PHF20 | c.1092del p.E364Dfs*7 | Frame Shift Del (DEL) | VAF 24/122 reads (20%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.1145C>A p.P382H | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRRC2B | c.2255T>C p.L752P | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PSEN1 | c.722T>C p.L241P | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEPTIN9 | c.826T>C p.F276L (on ENST00000427177 / NM_001113491.2; = p.F258L on NM_006640.4) | Missense Mutation (SNP) | VAF 113/401 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SI | c.2210G>C p.G737A | Missense Mutation (SNP) | VAF 85/317 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SLC35F1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.021); called by muse, mutect2
- SLC37A3 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SMTNL1 | c.1098C>G p.F366L (on ENST00000399154; = p.F403L on NM_001105565.2) | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPRED3 | c.1129G>T p.V377L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- STAG1 | c.300C>A p.S100= | Splice Region (SNP) | VAF 72/211 reads (34%) | called by muse, mutect2, varscan2
- TACC2 | c.7954C>A p.P2652T (on ENST00000334433; = p.P730T on NM_006997.4) | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- TACR3 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TFEC | c.173C>A p.S58* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | called by muse, varscan2
- TSPOAP1 | c.4796G>A p.G1599D | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TUBGCP3 | c.2496G>C p.R832S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- UBE2A | c.122T>G p.F41C | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP21 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- USP29 | c.2245C>G p.Q749E | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDR47 | c.1202A>G p.E401G (on ENST00000369962 / NM_001142551.2; = p.E402G on NM_014969.5) | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZMYM4 | c.2642A>C p.D881A | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZPBP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 32/116 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZSWIM5 | c.3200G>T p.S1067I | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ABCC11 | c.855C>T p.C285= | Silent (SNP) | VAF 21/176 reads (12%) | catalogued as rs138005798, COSV100750500; called by muse, mutect2, varscan2
- CCIN | c.1125G>A p.G375= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs17851732, COSV100631678, COSV58725995; called by muse, mutect2, varscan2
- CUBN | c.1440A>C p.G480= | Silent (SNP) | VAF 90/346 reads (26%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1023G>A p.K341= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as rs371562156; called by muse, mutect2, varscan2
- FRMPD4 | c.3138A>T p.G1046= | Silent (SNP) | VAF 67/116 reads (58%) | called by muse, mutect2, varscan2
- GAB4 | c.1503C>T p.S501= | Silent (SNP) | VAF 26/227 reads (11%) | catalogued as rs755347977, COSV68754459; called by muse, mutect2, varscan2
- GLI2 | c.3942C>T p.S1314= (on ENST00000361492 / NM_001374353.1; = p.S1331= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- GPHN | c.1665C>A p.L555= (on ENST00000315266 / NM_001377519.1; = p.L588= on NM_020806.5) | Silent (SNP) | VAF 62/289 reads (21%) | called by muse, mutect2, varscan2
- IFFO2 | c.1302G>A p.T434= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV62913255; called by muse, mutect2, varscan2
- JUNB | c.381C>T p.G127= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as rs776344055; called by muse, mutect2, varscan2
- KLHDC7A | c.1956G>A p.A652= | Silent (SNP) | VAF 65/221 reads (29%) | catalogued as rs1035779858; called by muse, mutect2, varscan2
- MARVELD1 | c.189C>T p.F63= | Silent (SNP) | VAF 102/381 reads (27%) | catalogued as rs1171788759; called by muse, mutect2, varscan2
- NEURL2 | c.834T>C p.L278= | Silent (SNP) | VAF 42/132 reads (32%) | called by muse, mutect2, varscan2
- RYR2 | c.8019G>A p.A2673= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as rs745484020, COSV63711534; called by muse, mutect2
- TADA2A | c.1299C>T p.F433= | Silent (SNP) | VAF 27/105 reads (26%) | called by muse, mutect2, varscan2
- TBC1D9 | c.60C>A p.A20= | Silent (SNP) | VAF 41/188 reads (22%) | called by muse, varscan2
- TRIM3 | c.921A>C p.R307= | Silent (SNP) | VAF 50/328 reads (15%) | called by muse, mutect2, varscan2
- UTP20 | c.1896C>T p.P632= | Silent (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- ANKLE2 | c.1700+37C>G | Intron (SNP) | VAF 61/195 reads (31%) | called by muse, mutect2, varscan2
- CASZ1 | c.506-85_506-78delinsA | Intron (DEL) | VAF 16/53 reads (30%) | called by pindel, varscan2*
- CHRNA4 | c.*3184G>T | 3'UTR (SNP) | VAF 34/308 reads (11%) | called by muse, varscan2
- CHRNA4 | c.*3177C>T | 3'UTR (SNP) | VAF 40/278 reads (14%) | called by muse, varscan2
- CRPPA | c.*2415C>T | 3'UTR (SNP) | VAF 24/132 reads (18%) | called by muse, varscan2
- GYS1 | c.*918A>G | 3'UTR (SNP) | VAF 148/530 reads (28%) | catalogued as rs1484203468; called by muse, mutect2, varscan2
- MEFV | c.1356+404C>T | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as rs1314217162; called by muse, mutect2, varscan2
- PDHA1 | c.57+1651dup | Intron (INS) | VAF 6/23 reads (26%) | called by pindel, varscan2
- PDIA3P1 | n.1265G>T | RNA (SNP) | VAF 83/258 reads (32%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159236 G>A | 5'Flank (SNP) | VAF 13/95 reads (14%) | catalogued as rs761417825; called by muse, mutect2, varscan2
- SAMHD1 | c.1154+49G>T | Intron (SNP) | VAF 50/184 reads (27%) | called by muse, varscan2
- STON1 | chr2:48530122 T>C | 5'Flank (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- TUBB8P7 | n.894+216C>G | Intron (SNP) | VAF 89/323 reads (28%) | catalogued as rs556213255; called by muse, mutect2, varscan2
- UMPS | c.*1306G>A | 3'UTR (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- VAPB | c.*6170A>G | 3'UTR (SNP) | VAF 49/442 reads (11%) | catalogued as rs1172185375; called by muse, mutect2, varscan2
